Somatic mutation profile of tumor specimen TCGA-B8-5162-01A (aliquot TCGA-B8-5162-01A-01D-1421-08) from TCGA case TCGA-B8-5162, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 63.0 years (23,008 days).
Specimen TCGA-B8-5162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2d6346a-8af7-4778-bb58-37a76bd1b0be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5162-10A (Blood Derived Normal), aliquot TCGA-B8-5162-10A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d67e3148-7ae5-416c-8bca-7dfa826057cd

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Frame Shift Del 5, 5'Flank 2, Nonsense Mutation 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55597650; called by muse, mutect2, varscan2
- ACAP1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs772255797, COSV50139666; called by mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, mutect2, varscan2
- AGAP3 | c.1248G>C p.E416D (on ENST00000622464; = p.E452D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV68246152; called by muse, mutect2, varscan2
- ANK2 | c.7229A>C p.E2410A | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52180371; called by muse, mutect2, varscan2
- AP2B1 | c.449A>T p.D150V | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV52002099; called by muse, mutect2, varscan2
- CEP250 | c.5143G>A p.G1715S | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as rs757984729, COSV61172942; called by muse, mutect2, varscan2
- CHD1 | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52343670; called by muse, mutect2, varscan2
- CLEC4E | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100222750, COSV55226871; called by muse, varscan2
- EDRF1 | c.1278A>T p.A426= (on ENST00000356792 / NM_001202438.2; = p.A392= on NM_015608.2) | Splice Region (SNP) | VAF 16/157 reads (10%) | catalogued as COSV61765698; called by muse, mutect2, varscan2
- F13A1 | c.1971A>C p.L657F | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV53564764; called by muse, mutect2, varscan2
- FAM8A1 | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52582763; called by muse, varscan2
- FRZB | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54555564; called by muse, mutect2, varscan2
- FUS | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV54219163; called by muse, mutect2, varscan2
- GET4 | c.242G>C p.S81T | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56256257, COSV56256415; called by muse, mutect2, varscan2
- IK | c.1173T>A p.D391E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV70258137; called by muse, mutect2, varscan2
- ISOC1 | c.874T>A p.S292T | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.07); catalogued as COSV51492628; called by muse, mutect2, varscan2
- ITPK1 | c.143A>C p.E48A | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV50898525; called by muse, mutect2, varscan2
- KCNS2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54640259; called by muse, mutect2, varscan2
- L3MBTL2 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs764867743, COSV53435107; called by muse, mutect2, varscan2
- LAMC1 | c.2480T>A p.L827Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as COSV51163850; called by muse, mutect2
- LRRIQ1 | c.2554A>T p.I852F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67836252; called by muse, mutect2, varscan2
- LVRN | c.1494T>G p.F498L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63498072; called by muse, mutect2, varscan2
- MAPKAPK2 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV54317925, COSV99685654; called by muse, mutect2
- MERTK | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs755422343, COSV54933937; called by muse, mutect2, varscan2
- MYH7 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs730880830, COSV62522428; ClinVar: uncertain significance; called by muse, mutect2
- NDST4 | c.1950C>A p.D650E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as COSV52131791; called by muse, varscan2
- NIPBL | c.6659T>A p.L2220* | Nonsense Mutation (SNP) | VAF 35/211 reads (17%) | catalogued as COSV56950499, COSV56961496; called by muse, mutect2, varscan2
- PAIP1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 80/442 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV59087118; called by muse, mutect2, varscan2
- PNLIP | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV65039889; called by muse, mutect2
- POLR1A | c.4016T>G p.L1339R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55697667; called by muse, mutect2
- PPHLN1 | c.162T>A p.S54R | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as COSV56735060; called by muse, mutect2, varscan2
- PPP3CC | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV51502815; called by muse, mutect2, varscan2
- PTAR1 | c.894C>A p.F298L | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61209290; called by muse, mutect2, varscan2
- QSER1 | c.99C>A p.G33= (on ENST00000399302; = p.G162= on NM_001076786.3) | Splice Region (SNP) | VAF 26/148 reads (18%) | catalogued as COSV67901455; called by muse, mutect2, varscan2
- RND3 | c.697T>G p.L233V | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55725613; called by muse, mutect2
- RPRD2 | c.4081G>T p.G1361C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV64822636; called by muse, mutect2, varscan2
- SLC25A39 | c.1011G>A p.M337I (on ENST00000377095 / NM_001143780.3; = p.M329I on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56588770; called by muse, mutect2, varscan2
- SMU1 | c.369G>C p.R123S | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV68140212; called by muse, mutect2, varscan2
- SYT6 | c.671C>G p.S224C (on ENST00000610222 / NM_001366225.1; = p.S139C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV65775560; called by muse, mutect2, varscan2
- TEK | c.2936A>C p.K979T | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66231957; called by muse, mutect2, varscan2
- TRIOBP | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV60378597, COSV60382673; called by muse, mutect2, varscan2
- UBOX5 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV53908473; called by muse, mutect2, varscan2
- UBR4 | c.15134T>C p.I5045T | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV64396355; called by muse, mutect2
- USP1 | c.1177G>C p.G393R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV60575178; called by muse, mutect2, varscan2
- VHL | c.397_398delinsT p.T133Lfs*26 | Frame Shift Del (DEL) | VAF 41/367 reads (11%) | catalogued as COSV56562219; called by pindel, varscan2*
- XPO7 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV53018738; called by muse, mutect2, varscan2
- ZNF609 | c.2738C>A p.P913H | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV58588306; called by muse, mutect2, varscan2
- ZSCAN31 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60181531; called by muse, mutect2, varscan2
- ITIH2 | c.2386_2387del p.T796Gfs*24 | Frame Shift Del (DEL) | VAF 22/189 reads (12%) | called by pindel, varscan2
- NDST4 | c.1958del p.P653Lfs*64 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by pindel, varscan2
- PASK | c.499del p.L167Sfs*6 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- SAMD3 | c.1313del p.N438Tfs*14 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | called by mutect2, pindel, varscan2
- SCAF4 | c.1726_1728+3del p.X576_splice | Splice Site (DEL) | VAF 23/187 reads (12%) | called by mutect2, pindel, varscan2
- C10orf62 | c.51A>T p.P17= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV65705487; called by muse, mutect2, varscan2
- DAB2 | c.2235A>G p.S745= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV100298239; called by mutect2, varscan2
- DCSTAMP | c.855G>A p.P285= | Silent (SNP) | VAF 37/249 reads (15%) | catalogued as rs553927963, COSV52579386; called by muse, mutect2, varscan2
- DMGDH | c.726T>C p.N242= | Silent (SNP) | VAF 63/424 reads (15%) | catalogued as COSV54867479; called by muse, mutect2, varscan2
- FBXW10 | c.2085G>A p.T695= | Silent (SNP) | VAF 61/311 reads (20%) | catalogued as rs759505188, COSV57315064; called by muse, mutect2, varscan2
- GLRX5 | c.342C>T p.L114= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV58763882; called by muse, mutect2, varscan2
- KEL | c.397C>T p.L133= | Silent (SNP) | VAF 48/279 reads (17%) | catalogued as rs779027143, COSV62337056; called by muse, mutect2, varscan2
- MYO1B | c.72A>G p.E24= | Silent (SNP) | VAF 34/246 reads (14%) | catalogued as COSV58436269; called by muse, mutect2, varscan2
- OR5K1 | c.108G>A p.L36= | Silent (SNP) | VAF 60/346 reads (17%) | catalogued as COSV60305030; called by muse, mutect2, varscan2
- PGM3 | c.1272G>A p.L424= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV52285472; called by muse, mutect2
- SAMD9 | c.675T>C p.A225= | Silent (SNP) | VAF 61/373 reads (16%) | catalogued as COSV66077066; called by muse, mutect2, varscan2
- SLC16A9 | c.852G>A p.K284= | Silent (SNP) | VAF 50/372 reads (13%) | catalogued as COSV68100126; called by muse, mutect2, varscan2
- ZNF226 | c.816G>A p.Q272= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV56197665; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505975 G>C | 5'Flank (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- EXOC3 | chr5:442605 C>T | 5'Flank (SNP) | VAF 35/233 reads (15%) | catalogued as rs201231253; called by muse, mutect2, varscan2
